Somatic mutation profile of tumor specimen TCGA-D3-A8GD-06A (aliquot TCGA-D3-A8GD-06A-11D-A372-08) from TCGA case TCGA-D3-A8GD, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.4 years (23,151 days).
Specimen TCGA-D3-A8GD-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8823b4a-5847-4466-9f02-85b0fe6f7294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GD-10A (Blood Derived Normal), aliquot TCGA-D3-A8GD-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24331339-988a-432b-bd71-4917279570cd

The open-access MAF lists 112 somatic variants for this specimen: 88 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 22, Splice Site 3, Frame Shift Del 2, Nonsense Mutation 2, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AC100868.1 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99226918; called by muse, mutect2, varscan2
- ADGRB3 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101001992; called by muse, mutect2, varscan2
- AKAP1 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV100028260; called by muse, mutect2
- ANK2 | c.4454C>T p.S1485F | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100004300; called by muse, mutect2, varscan2
- ANKRD30A | c.3148G>A p.E1050K (on ENST00000611781; = p.E994K on NM_052997.2) | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1237785275, COSV64605238; called by muse, mutect2, varscan2
- ASPSCR1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149772045; called by muse, mutect2, varscan2
- C1orf116 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760559013; called by muse, mutect2, varscan2
- CCDC87 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as rs749023439, COSV100040191, COSV59578802; called by muse, mutect2, varscan2
- CDH6 | c.526A>G p.T176A | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV54075091, COSV99420892; called by muse, mutect2, varscan2
- CDKL5 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV66110150; called by muse, mutect2, varscan2
- CEP126 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 66/238 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99681440; called by muse, mutect2, varscan2
- CEP152 | c.691+1G>C p.X231_splice | Splice Site (SNP) | VAF 6/110 reads (5%) | catalogued as COSV100359183; called by muse, mutect2
- CFAP206 | c.389T>A p.L130H | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99740152; called by muse, mutect2, varscan2
- CFAP54 | c.7616C>T p.P2539L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.14); catalogued as COSV100733284, COSV100733346; called by muse, mutect2, varscan2
- COL12A1 | c.8688A>T p.G2896= | Splice Region (SNP) | VAF 11/103 reads (11%) | catalogued as COSV100486563; called by muse, mutect2, varscan2
- COL12A1 | c.4954A>G p.T1652A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100486565; called by muse, mutect2, varscan2
- COL21A1 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs538369254, COSV99780303; called by muse, mutect2, varscan2
- COL28A1 | c.2725T>C p.S909P | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV101258951; called by muse, mutect2, varscan2
- COL5A2 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100880833; called by muse, varscan2
- COL5A2 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100880835; called by muse, mutect2, varscan2
- COL6A3 | c.8795C>T p.P2932L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99801579; called by muse, mutect2
- DUS2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs1567470923, COSV100732680; called by muse, mutect2, varscan2
- ETF1 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs1350240517, COSV100860281; called by muse, mutect2, varscan2
- FAM47B | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61454205; called by muse, mutect2
- FCGR2A | c.471C>G p.F157L (on ENST00000271450 / NM_001136219.3; = p.F156L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as COSV99615739; called by muse, mutect2
- FER | c.269A>G p.E90G | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs1298797546, COSV99813983; called by muse, mutect2, varscan2
- GHDC | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100054981; called by muse, mutect2
- GPRASP1 | c.350T>G p.I117R | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100851081; called by muse, mutect2, varscan2
- GPRIN2 | c.887T>A p.L296H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.437); catalogued as COSV100966485; called by muse, mutect2
- GRIK4 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV70807241; called by muse, varscan2
- GULP1 | c.610-1G>A p.X204_splice | Splice Site (SNP) | VAF 22/167 reads (13%) | catalogued as rs1172164440, COSV100771213; called by muse, mutect2, varscan2
- HARBI1 | c.501C>G p.N167K | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100366043; called by muse, mutect2, varscan2
- HMCN1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs1307182815, COSV99635981; called by muse, mutect2, varscan2
- IGHV3-30 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 50/476 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); catalogued as rs775745945; called by muse, mutect2
- KERA | c.766T>G p.S256A | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1333689304, COSV99899595; called by muse, mutect2, varscan2
- KIAA0319 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as COSV100985819, COSV99068301; called by muse, mutect2
- LMOD1 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs992229692, COSV66172365; called by muse, mutect2
- LVRN | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs367939302, COSV63497362; called by muse, mutect2, varscan2
- LYPLA1 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1214161346, COSV100387420; called by muse, mutect2, varscan2
- MAGEC1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs1244386145, COSV99596597; called by muse, varscan2
- MARK1 | c.2258T>A p.V753E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100857574; called by muse, mutect2, varscan2
- MEP1A | c.2141T>C p.V714A | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as COSV100043128; called by muse, mutect2, varscan2
- MYH8 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 45/234 reads (19%) | catalogued as COSV101238815; called by muse, mutect2, varscan2
- NUP210 | c.1031A>G p.E344G | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99597066; called by muse, mutect2, varscan2
- OLFM2 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as rs199678889, COSV99322060; called by mutect2, varscan2
- OR13F1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100594857; called by muse, mutect2, varscan2
- OR5H14 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765393898, COSV71194285; called by muse, mutect2, varscan2
- PARP4 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); catalogued as rs370048875, COSV67963054; called by muse, mutect2, varscan2
- PARP8 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99892845; called by muse, mutect2
- PCDHB1 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs781949354, COSV100128423; called by muse, varscan2
- PEG10 | c.764G>A p.R255Q (on ENST00000482108 / NM_001040152.2; = p.R289Q on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV71788769; called by muse, mutect2, varscan2
- PIK3CD | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100740548; called by muse, mutect2
- PITRM1 | c.2175G>T p.R725S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.999); catalogued as rs1402933936, COSV99829692; called by muse, mutect2, varscan2
- PLG | c.1713A>C p.Q571H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as COSV100369585; called by muse, mutect2
- PRDM4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV99946742; called by muse, mutect2
- PTEN | c.769T>C p.F257L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as COSV100911354; called by muse, mutect2, varscan2
- RAG1 | c.1900A>G p.I634V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1263385083, COSV100201175; called by muse, mutect2, varscan2
- RAI2 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 15/193 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV100518539; called by muse, mutect2
- RAPGEF6 | c.4720A>G p.N1574D | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.013); catalogued as rs1469448412, COSV99727994; called by muse, mutect2, varscan2
- RFPL4B | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV101480727; called by muse, mutect2, varscan2
- RNF213 | c.14854G>A p.D4952N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); catalogued as rs751812499, COSV100301534; called by muse, mutect2, varscan2
- SAMD9 | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1442318478, COSV66076942; called by muse, mutect2, varscan2
- SCAND1 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as rs1003037227, COSV100019004; called by muse, mutect2
- SCN11A | c.2851C>T p.Q951* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs1553635777, COSV100182601; called by muse, mutect2, varscan2
- SERPINB5 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.305); catalogued as rs1352255563, COSV101237564; called by muse, mutect2, varscan2
- SEZ6L | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs267606204, COSV50675868; called by muse, mutect2, varscan2
- SH3TC1 | c.2604G>A p.M868I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs1303938821, COSV99795337; called by muse, mutect2, varscan2
- SLC4A11 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs761571805, COSV101195935; called by muse, mutect2, varscan2
- SLC9A1 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99850052; called by muse, mutect2, varscan2
- SLITRK1 | c.1255T>G p.F419V | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000071; called by muse, mutect2, varscan2
- SLITRK5 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61523074; called by muse, mutect2, varscan2
- SLX4IP | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100570889; called by muse, mutect2, varscan2
- SRPK2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1286660967, COSV61963949; called by muse, mutect2, varscan2
- TDRD1 | c.3451G>T p.V1151F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99315173; called by mutect2, varscan2
- THEMIS | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.051); catalogued as COSV100965592; called by muse, mutect2, varscan2
- TMEM81 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99196894, COSV99196904; called by muse, mutect2, varscan2
- TNS1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs571848557, COSV99410809, COSV99411954; called by muse, mutect2, varscan2
- TTF2 | c.2564A>G p.Y855C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101037862; called by muse, mutect2, varscan2
- USH2A | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56433542; called by muse, mutect2, varscan2
- USP25 | c.931+1G>T p.X311_splice | Splice Site (SNP) | VAF 7/151 reads (5%) | catalogued as COSV99584616; called by muse, mutect2
- VSIG4 | c.315G>C p.M105I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.152); catalogued as COSV101038325, COSV66074070; called by muse, mutect2
- ZNF224 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100425537; called by muse, mutect2, varscan2
- ZNF254 | c.1784T>C p.I595T | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV61642479; called by muse, mutect2, varscan2
- ZNF318 | c.5781A>C p.E1927D | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.275); catalogued as COSV100546534; called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | called by pindel, varscan2
- KIFAP3 | c.2272del p.S758Afs*66 | Frame Shift Del (DEL) | VAF 33/184 reads (18%) | called by mutect2, pindel*, varscan2
- MUC17 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 86/746 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AOPEP | c.2265G>A p.K755= (on ENST00000375315 / NM_001193329.1; = p.K656= on NM_032823.5) | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV99950926; called by muse, mutect2, varscan2
- AXDND1 | c.337C>T p.L113= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs763611000, COSV100858325, COSV100858682; called by muse, mutect2, varscan2
- CHST9 | c.1290C>T p.Y430= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99410970; called by muse, mutect2, varscan2
- GRID2 | c.2253C>T p.I751= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV99947035; called by muse, mutect2, varscan2
- HPCAL4 | c.324C>T p.Y108= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100864818; called by mutect2, varscan2
- LCE1C | c.246C>T p.R82= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV100908488; called by muse, mutect2, varscan2
- MCMDC2 | c.1605C>T p.F535= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV100552327; called by muse, mutect2, varscan2
- MYCBPAP | c.975G>A p.L325= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100089132; called by muse, mutect2
- NUP210 | c.3237C>T p.P1079= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1423357321, COSV99597064; called by muse, mutect2, varscan2
- OR2M2 | c.744G>T p.V248= | Silent (SNP) | VAF 64/302 reads (21%) | catalogued as rs950032456, COSV100677319; called by muse, mutect2, varscan2
- PCNX3 | c.3654C>A p.S1218= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV100856654; called by muse, mutect2, varscan2
- PIGQ | c.1464G>A p.V488= | Silent (SNP) | VAF 32/151 reads (21%) | catalogued as COSV99216556; called by muse, mutect2, varscan2
- PLCG2 | c.219C>A p.I73= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100842669; called by muse, mutect2, varscan2
- PLEKHO2 | c.1179C>T p.D393= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100060968; called by muse, mutect2, varscan2
- POU2F1 | c.516C>T p.I172= (on ENST00000541643 / NM_001365848.1; = p.I195= on NM_002697.4) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs562014026, COSV99611314; called by muse, mutect2, varscan2
- PRSS21 | c.897A>T p.L299= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV99135729; called by muse, mutect2, varscan2
- RBBP6 | c.1578G>A p.R526= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100154988; called by muse, mutect2, varscan2
- SLC2A12 | c.975C>T p.V325= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs537218720, COSV99260595; called by muse, mutect2, varscan2
- SLC35A4 | c.735C>T p.L245= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100021519; called by muse, mutect2
- SLC35A4 | c.736C>T p.L246= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100021520; called by muse, mutect2
- USP6 | c.2868A>G p.R956= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100004945; called by muse, mutect2, varscan2
- XRCC1 | c.504C>G p.T168= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53453674, COSV99486753; called by muse, mutect2
- TGM2 | c.-1C>T | 5'UTR (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100821766; called by muse, mutect2, varscan2
- TGM2 | c.-2C>T | 5'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100821767; called by muse, mutect2, varscan2
